Somatic mutation profile of tumor specimen MP2PRT-PARPWV-TMP1-A (aliquot MP2PRT-PARPWV-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARPWV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,866 days).
Specimen MP2PRT-PARPWV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 796f70fa-b35c-4441-93f4-f8b6ed732094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPWV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPWV-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d5b1977-04bf-4082-acbc-f1566751a5ac

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 13, Nonsense Mutation 6, Frame Shift Ins 4, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.5985C>A p.Y1995* (on ENST00000333535 / NM_198056.3; = p.Y1994* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 76/444 reads (17%) | catalogued as rs794728941; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 136/331 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs202002337, COSV55948635, COSV99713868; called by muse, mutect2, varscan2
- ADAMDEC1 | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV56474857; called by muse, mutect2, varscan2
- ADAMTS20 | c.4112C>T p.S1371L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV67131096; called by muse, mutect2, varscan2
- CD59 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs146075291; called by muse, mutect2
- GRIN2C | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1239370949, COSV53111265; called by muse, mutect2, varscan2
- H2BC15 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 68/498 reads (14%) | catalogued as rs1474901744, COSV57586761; called by muse, mutect2, varscan2
- KANSL1 | c.2513C>G p.S838C | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs746688275; called by muse, mutect2
- KIAA0586 | c.3535C>T p.Q1179* (on ENST00000619416 / NM_001244190.2; = p.Q1118* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 38/289 reads (13%) | catalogued as rs373763986, COSV99709144; called by muse, mutect2, varscan2
- NMD3 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV63618797; called by muse, mutect2, varscan2
- SCML2 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 12/190 reads (6%) | catalogued as rs1478381870; called by muse, mutect2
- SLIT2 | c.3117C>G p.F1039L | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56595171; called by muse, mutect2, varscan2
- TIGD6 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs768843860, COSV57060509; called by muse, mutect2, varscan2
- ZNF423 | c.1483G>A p.E495K (on ENST00000563137 / NM_001379286.1; = p.E487K on NM_015069.4) | Missense Mutation (SNP) | VAF 68/489 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as rs866711600, COSV52178798; called by muse, mutect2, varscan2
- AMTN | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC124 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 77/444 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CFAP20DC | c.943_944insGG p.L315Rfs*2 (on ENST00000482387 / NM_001351530.2; = p.L190Rfs*2 on NM_198463.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 47/245 reads (19%) | called by mutect2, pindel, varscan2
- DPYSL4 | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KIDINS220 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MX1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.044); called by muse, varscan2
- NSD2 | c.3487C>G p.L1163V | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHA7 | c.800C>G p.S267* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SETD2 | c.1507_1508insGGCCCCG p.E503Gfs*19 | Frame Shift Ins (INS) | VAF 30/157 reads (19%) | called by mutect2, varscan2
- SETD2 | c.1506delinsGGGGCCCC p.E503Gfs*19 | Frame Shift Ins (INS) | VAF 37/176 reads (21%) | called by mutect2*, pindel, varscan2*
- STAB2 | c.4921G>C p.D1641H | Missense Mutation (SNP) | VAF 10/335 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); called by muse, mutect2
- TBL1XR1 | c.271_272insGGGG p.V91Gfs*11 | Frame Shift Ins (INS) | VAF 94/245 reads (38%) | called by mutect2, pindel, varscan2
- TRIM33 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 32/162 reads (20%) | called by muse, mutect2, varscan2
- ZNF254 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ART4 | c.843G>A p.Q281= | Silent (SNP) | VAF 35/96 reads (36%) | called by muse, mutect2, varscan2
- ATP8B2 | c.769C>T p.L257= (on ENST00000672630; = p.L224= on NM_001005855.2) | Silent (SNP) | VAF 56/394 reads (14%) | called by muse, mutect2, varscan2
- CDH5 | c.1983G>A p.S661= | Silent (SNP) | VAF 293/692 reads (42%) | catalogued as rs763725672; called by muse, mutect2, varscan2
- CYP2D6 | c.852G>C p.G284= | Silent (SNP) | VAF 72/481 reads (15%) | catalogued as COSV62243324; called by muse, mutect2, varscan2
- KIF21B | c.684C>T p.I228= | Silent (SNP) | VAF 63/502 reads (13%) | called by muse, mutect2, varscan2
- MELTF | c.759C>T p.F253= | Silent (SNP) | VAF 62/397 reads (16%) | catalogued as rs768912729, COSV56383280; called by muse, mutect2, varscan2
- MUC5B | c.14178C>T p.S4726= | Silent (SNP) | VAF 105/717 reads (15%) | catalogued as COSV71591354; called by muse, mutect2, varscan2
- NCAM1 | c.255C>T p.N85= | Silent (SNP) | VAF 75/391 reads (19%) | catalogued as rs540286134; called by muse, mutect2, varscan2
- RASAL2 | c.3264G>A p.R1088= | Silent (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- SCN8A | c.675G>A p.L225= | Silent (SNP) | VAF 43/248 reads (17%) | catalogued as rs1161949273, COSV61992996; called by muse, mutect2, varscan2
- SHKBP1 | c.2031C>G p.L677= | Silent (SNP) | VAF 67/537 reads (12%) | catalogued as COSV52540199; called by muse, mutect2, varscan2
- VPS4B | c.228G>A p.L76= | Silent (SNP) | VAF 95/236 reads (40%) | catalogued as rs755964017, COSV53069010; called by muse, mutect2, varscan2
- ZNF480 | c.300G>C p.G100= | Silent (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
- BCAN | c.1942+68C>G | Intron (SNP) | VAF 45/266 reads (17%) | called by muse, mutect2, varscan2
- PTRH1 | c.96+69G>A | Intron (SNP) | VAF 72/486 reads (15%) | called by muse, mutect2, varscan2
- ZKSCAN5 | c.*1204G>C | 3'UTR (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2, varscan2
